Somatic mutation profile of tumor specimen TCGA-EB-A4XL-01A (aliquot TCGA-EB-A4XL-01A-11D-A27K-08) from TCGA case TCGA-EB-A4XL, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 56.1 years (20,486 days).
Specimen TCGA-EB-A4XL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b875569-40a8-48b1-8083-289689790d30.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A4XL-10A (Blood Derived Normal), aliquot TCGA-EB-A4XL-10A-01D-A27N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15ea8df7-087a-4e78-84b6-22b3aec0e440

The open-access MAF lists 545 somatic variants for this specimen: 364 protein-altering or splice-affecting, 170 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 334, Silent 170, Nonsense Mutation 22, RNA 4, Splice Region 4, Splice Site 3, Intron 3, 5'Flank 2, 5'UTR 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABAT | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs757076760, COSV51620440; called by muse, mutect2, varscan2
- ABCA3 | c.1113C>T p.A371= | Splice Region (SNP) | VAF 32/86 reads (37%) | catalogued as COSV100069073; called by muse, mutect2, varscan2
- ABCA6 | c.3996G>A p.M1332I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.21); catalogued as COSV99447568; called by muse, mutect2
- ABCB5 | c.2711T>G p.L904R (on ENST00000404938 / NM_001163941.2; = p.L459R on NM_178559.6) | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV99329411; called by muse, mutect2, varscan2
- ABHD17A | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 29/136 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99171366; called by muse, mutect2, varscan2
- ABL2 | c.1637C>G p.S546C (on ENST00000502732 / NM_007314.4; = p.S531C on NM_005158.5) | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100772943; called by muse, mutect2, varscan2
- ADAM21 | c.1973C>T p.S658F | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV99961425; called by muse, mutect2, varscan2
- ADAM29 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs537404539, COSV63660881; called by muse, mutect2, varscan2
- ADAMTS19 | c.1246A>C p.K416Q | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.081); catalogued as COSV99180373; called by muse, mutect2, varscan2
- ADAMTS20 | c.5018G>A p.G1673E | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101240229; called by muse, mutect2, varscan2
- ADGRG1 | c.714G>C p.W238C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV101113546; called by muse, mutect2, varscan2
- ADGRG4 | c.5558C>T p.S1853F | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV54955296; called by muse, mutect2, varscan2
- ADGRV1 | c.15737G>A p.R5246Q | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs772037044, COSV67991803; called by muse, mutect2, varscan2
- AGBL1 | c.2675G>A p.R892Q | Missense Mutation (SNP) | VAF 84/181 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs774676310, COSV66862130; called by muse, mutect2, varscan2
- AGPAT4 | c.1065G>A p.M355I | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as COSV100211965; called by muse, mutect2
- AGTR2 | c.1079C>T p.T360I | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.051); catalogued as rs781859082, COSV100903621; called by muse, mutect2, varscan2
- AHI1 | c.1772C>T p.P591L | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.225); catalogued as COSV99663615; called by muse, mutect2, varscan2
- AHR | c.722G>A p.G241E | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99620180; called by muse, mutect2, varscan2
- ALDH1L1 | c.2062C>T p.L688F | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as COSV99857459; called by muse, mutect2, varscan2
- ALS2 | c.3294C>A p.D1098E | Missense Mutation (SNP) | VAF 87/242 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); catalogued as COSV99969995; called by muse, mutect2, varscan2
- AMD1 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs757824536, COSV64387867; called by muse, mutect2, varscan2
- APBA3 | c.227C>T p.P76L | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.149); catalogued as rs1343066427, COSV100349757; called by muse, mutect2, varscan2
- APBB2 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV55964976, COSV99924008; called by muse, mutect2, varscan2
- ARHGEF11 | c.2009C>T p.P670L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1050814611, COSV100168913; called by muse, mutect2, varscan2
- ARID1B | c.4519C>T p.Q1507* | Nonsense Mutation (SNP) | VAF 55/129 reads (43%) | catalogued as rs1554235845, COSV99271608; called by muse, mutect2, varscan2
- ARPP21 | c.1510A>C p.T504P | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as COSV99493145; called by muse, mutect2, varscan2
- ARSG | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.017); catalogued as COSV101477922; called by muse, mutect2, varscan2
- ASIC5 | c.1306G>A p.V436M | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV101611168; called by muse, mutect2, varscan2
- ASMT | c.982G>A p.D328N (on ENST00000381229; = p.D356N on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV101172530; called by muse, mutect2, varscan2
- ASTN1 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.156); catalogued as COSV56060961; called by muse, mutect2, varscan2
- ASXL3 | c.4108C>T p.P1370S | Missense Mutation (SNP) | VAF 37/130 reads (28%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as rs1349869581, COSV52458378; called by muse, mutect2, varscan2
- ATM | c.6295C>T p.H2099Y | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV99591667; called by muse, mutect2, varscan2
- ATP2B3 | c.527G>A p.W176* | Nonsense Mutation (SNP) | VAF 57/163 reads (35%) | catalogued as COSV99685690; called by muse, mutect2, varscan2
- ATRNL1 | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV100369303, COSV100372627, COSV99049658; called by muse, mutect2, varscan2
- BAG5 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758744586, COSV99915014; called by muse, mutect2, varscan2
- BIRC6 | c.11557C>T p.H3853Y | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1254039883, COSV101428775; called by muse, mutect2, varscan2
- BLK | c.959T>C p.L320P | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs111982490, COSV99377568; called by muse, mutect2, varscan2
- BPIFB2 | c.281C>A p.A94E | Missense Mutation (SNP) | VAF 54/160 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.474); catalogued as rs749731259, COSV99401646; called by muse, mutect2, varscan2
- C11orf49 | c.414T>A p.D138E | Missense Mutation (SNP) | VAF 94/241 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV99562694; called by muse, mutect2, varscan2
- C2orf16 | c.3551G>A p.R1184K | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV100820978; called by muse, mutect2, varscan2
- CADM4 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV99731676; called by muse, mutect2, varscan2
- CALCR | c.636G>A p.M212I (on ENST00000649521 / NM_001164737.2; = p.M196I on NM_001742.4) | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64012166; called by muse, mutect2, varscan2
- CAMK1 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV99844918; called by muse, mutect2, varscan2
- CAMTA1 | c.3747C>A p.N1249K | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as COSV100352236; called by muse, mutect2, varscan2
- CAPZA3 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs577490193, COSV99856891; called by muse, mutect2, varscan2
- CARMIL1 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.16); catalogued as COSV100278745; called by muse, mutect2, varscan2
- CATSPERB | c.2132G>A p.W711* | Nonsense Mutation (SNP) | VAF 33/95 reads (35%) | catalogued as rs1209412832, COSV99831683; called by muse, mutect2, varscan2
- CBLIF | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.071); catalogued as COSV99951079; called by muse, mutect2, varscan2
- CCDC141 | c.2765A>T p.N922I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99837401; called by muse, mutect2, varscan2
- CD163 | c.2384T>G p.I795S | Missense Mutation (SNP) | VAF 87/200 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV100776094; called by muse, mutect2, varscan2
- CDH23 | c.696G>A p.M232I | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.826); catalogued as rs768084499, COSV99823506; called by muse, mutect2
- CDH23 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.969); catalogued as COSV54928952; called by muse, mutect2
- CDH4 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV100848436; called by muse, mutect2, varscan2
- CFAP126 | c.290A>C p.Q97P | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as COSV100713766; called by muse, mutect2, varscan2
- CFAP206 | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV99740002; called by muse, mutect2
- CFAP45 | c.763A>G p.I255V | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100928659; called by muse, mutect2, varscan2
- CFAP54 | c.6419G>A p.G2140E | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61573137; called by muse, mutect2, varscan2
- CHD7 | c.5720C>T p.S1907L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV101418410; called by muse, mutect2, varscan2
- CHL1 | c.3245G>A p.W1082* (on ENST00000397491 / NM_001253387.1; = p.W1098* on NM_006614.4) | Nonsense Mutation (SNP) | VAF 49/138 reads (36%) | catalogued as rs1419779871, COSV99852207; called by muse, mutect2, varscan2
- CHRM3 | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 69/148 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs780261877, COSV99697438; called by muse, mutect2, varscan2
- CLDN19 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.558); catalogued as rs549476247, COSV99591743; called by muse, varscan2
- CLYBL | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100185680; called by muse, mutect2, varscan2
- CMYA5 | c.919C>T p.L307F | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.018); catalogued as COSV101484320; called by muse, mutect2, varscan2
- CNTN6 | c.2977A>T p.K993* | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100611762; called by muse, mutect2, varscan2
- COG6 | c.1592C>G p.A531G | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100743308; called by muse, mutect2, varscan2
- COL14A1 | c.3778C>T p.P1260S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs750135277, COSV99920499; called by muse, mutect2, varscan2
- COL15A1 | c.2117G>A p.G706E | Missense Mutation (SNP) | VAF 31/46 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1222127908, COSV100897959; called by muse, mutect2, varscan2
- COL21A1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55168981, COSV99780203; called by muse, mutect2, varscan2
- COL22A1 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV57329519; called by muse, mutect2
- COL4A4 | c.4562C>T p.P1521L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1222616093, COSV100307613; called by muse, mutect2, varscan2
- COL4A4 | c.3943C>T p.P1315S | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.999); catalogued as COSV61630789; called by muse, mutect2, varscan2
- COL5A2 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66412247; called by muse, mutect2, varscan2
- COL8A1 | c.1393G>A p.G465R | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99658367; called by muse, mutect2, varscan2
- COLEC10 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); catalogued as COSV100250868; called by muse, mutect2, varscan2
- CPAMD8 | c.1774C>T p.L592F (on ENST00000651564; = p.L545F on NM_015692.5) | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.94); catalogued as rs267605341, COSV99359763; called by muse, mutect2
- CR2 | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV65509215; called by muse, mutect2, varscan2
- CRNKL1 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs763086392, COSV55619227, COSV99844357; called by muse, mutect2, varscan2
- CSMD2 | c.8278C>T p.H2760Y | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV53919678, COSV99594690; called by muse, mutect2, varscan2
- CUX2 | c.1744G>A p.G582R | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99920637; called by muse, mutect2, varscan2
- CUX2 | c.1745G>A p.G582E | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99920640; called by muse, mutect2, varscan2
- CYSLTR1 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772170849, COSV100964748; called by muse, mutect2, varscan2
- DAGLA | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.012); catalogued as rs759559085, COSV99944697; called by muse, mutect2, varscan2
- DAO | c.476T>A p.F159Y | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV99948853; called by muse, mutect2, varscan2
- DCP2 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.169); catalogued as rs1467146317, COSV101203960; called by muse, mutect2, varscan2
- DDIT4L | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs751851511, COSV56767198; called by muse, mutect2, varscan2
- DHRS7C | c.565C>T p.R189C (on ENST00000330255 / NM_001220493.2; = p.R188C on NM_001105571.3) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779288165, COSV57653581; called by muse, mutect2, varscan2
- DNAH3 | c.4000C>T p.R1334* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as rs778730326, COSV99770266; called by muse, mutect2, varscan2
- DNAH9 | c.8323G>A p.E2775K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as rs754629782, COSV52337021; called by muse, mutect2, varscan2
- DNAH9 | c.8876G>A p.G2959E | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52350716; called by muse, varscan2
- DNAJC21 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100331583; called by muse, mutect2, varscan2
- DSCAM | c.1434C>A p.D478E | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV101261409, COSV68020523; called by muse, mutect2, varscan2
- DSCAML1 | c.2538G>A p.K846= (on ENST00000321322; = p.K786= on NM_020693.4) | Splice Region (SNP) | VAF 14/18 reads (78%) | catalogued as COSV100357059; called by muse, mutect2, varscan2
- DSG3 | c.2764A>T p.I922F | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV99934672; called by muse, mutect2
- EGFR | c.2944C>T p.Q982* | Nonsense Mutation (SNP) | VAF 46/95 reads (48%) | catalogued as COSV51801770, COSV99291764; called by muse, mutect2, varscan2
- ELF4 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.775); catalogued as COSV57454354; called by muse, mutect2, varscan2
- ELF4 | c.1668G>A p.M556I | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100257573; called by muse, mutect2, varscan2
- EMILIN3 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.202); catalogued as rs1184986387, COSV100182788; called by muse, mutect2, varscan2
- EP400 | c.6877C>T p.R2293C | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1433414794, COSV57763285; called by muse, mutect2, varscan2
- EPHA6 | c.2683G>A p.A895T (on ENST00000389672 / NM_001080448.3; = p.A287T on NM_173655.4) | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67559836; called by muse, mutect2, varscan2
- ERBB4 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751175543, COSV53515716; called by muse, mutect2, varscan2
- ERBIN | c.1981C>T p.P661S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs775311015, COSV99397723; called by muse, mutect2, varscan2
- ERBIN | c.2587C>T p.P863S | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99397725; called by muse, mutect2, varscan2
- ERC2 | c.50G>A p.R17K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as COSV99889232; called by muse, mutect2, varscan2
- EZHIP | c.332G>A p.G111E | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.399); catalogued as COSV100539883; called by muse, mutect2, varscan2
- F8 | c.4138G>A p.E1380K | Missense Mutation (SNP) | VAF 81/201 reads (40%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV64269762; called by muse, mutect2, varscan2
- F8A1 | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 101/689 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100371815; called by muse, mutect2, varscan2
- FAM135B | c.4124A>G p.N1375S | Missense Mutation (SNP) | VAF 125/365 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99427047; called by muse, mutect2, varscan2
- FAM177B | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as rs1390061571, COSV100680462; called by muse, mutect2, varscan2
- FAM71A | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54234557; called by muse, mutect2, varscan2
- FASN | c.5753C>T p.S1918F | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV100148270; called by muse, mutect2, varscan2
- FAT3 | c.5879G>A p.G1960E | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53124013; called by muse, mutect2, varscan2
- FGD5 | c.2033C>T p.S678F | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.614); catalogued as COSV53250934, COSV99549633; called by muse, mutect2, varscan2
- FILIP1 | c.584A>G p.N195S | Missense Mutation (SNP) | VAF 89/200 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as COSV99386008; called by muse, mutect2, varscan2
- FLG | c.8383G>A p.G2795R | Missense Mutation (SNP) | VAF 255/986 reads (26%) | SIFT tolerated (0.81); PolyPhen benign (0.007); catalogued as rs779385755, COSV64241727; called by muse, mutect2, varscan2
- FLG | c.4297G>A p.E1433K | Missense Mutation (SNP) | VAF 187/369 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs267598030, COSV64247369; called by muse, mutect2, varscan2
- FNDC1 | c.1219G>A p.G407R | Missense Mutation (SNP) | VAF 111/269 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99796633; called by muse, mutect2, varscan2
- FOXR2 | c.401C>T p.S134F | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as COSV59257898; called by muse, mutect2, varscan2
- FPR3 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs757959263, COSV100200850; called by muse, mutect2, varscan2
- FRMPD2 | c.2143G>A p.G715R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as COSV100564140; called by muse, mutect2, varscan2
- FRRS1 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.029); catalogued as rs149529384; called by muse, mutect2, varscan2
- FSHR | c.1814C>T p.S605F | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100437974; called by muse, mutect2, varscan2
- FSIP2 | c.16576G>A p.G5526R | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV100556269; called by muse, mutect2, varscan2
- FTMT | c.64G>A p.V22M | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); catalogued as rs972840686, COSV100360447; called by muse, mutect2, varscan2
- G6PD | c.631C>T p.L211F | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1327633245, COSV100855117; called by muse, mutect2, varscan2
- GJA4 | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV100654743; called by muse, mutect2, varscan2
- GPM6A | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV54555129; called by muse, mutect2, varscan2
- GPR148 | c.896G>A p.W299* | Nonsense Mutation (SNP) | VAF 44/116 reads (38%) | catalogued as COSV99998726; called by muse, mutect2, varscan2
- GPR89B | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV100032618; called by muse, mutect2
- GRIA1 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs764372850, COSV53617272; called by muse, mutect2, varscan2
- GRIN2A | c.3457G>A p.D1153N | Missense Mutation (SNP) | VAF 74/180 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); catalogued as rs267604687, COSV58027768; called by muse, mutect2, varscan2
- GTF2H4 | c.1292T>A p.L431H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99462198; called by muse, mutect2, varscan2
- GZMK | c.212+1G>A p.X71_splice | Splice Site (SNP) | VAF 17/39 reads (44%) | catalogued as COSV99140980; called by muse, mutect2, varscan2
- HCN1 | c.2405C>T p.S802F | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.365); catalogued as COSV57514686; called by muse, mutect2, varscan2
- HEPH | c.2408C>T p.P803L (on ENST00000343002; = p.P536L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs746936776, COSV100295607; called by muse, mutect2, varscan2
- HID1 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV100586086; called by muse, mutect2, varscan2
- HTR1A | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 78/218 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1403228466, COSV60501438, COSV60502125; called by muse, mutect2, varscan2
- HTR5A | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99839952, COSV99839961; called by muse, mutect2, varscan2
- HUWE1 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 63/155 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV99472043; called by muse, mutect2, varscan2
- IGHV1-24 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 75/197 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); catalogued as rs753109500; called by muse, mutect2, varscan2
- IMP4 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as rs267598873, COSV52091179; called by muse, mutect2, varscan2
- INAVA | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368201478; called by muse, mutect2
- INSRR | c.3067G>A p.E1023K | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV100948027; called by muse, mutect2, varscan2
- IQSEC3 | c.3464C>T p.P1155L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs760865332, COSV100407566; called by muse, varscan2
- IRF2BP1 | c.1154C>T p.P385L | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV100138996; called by muse, mutect2, varscan2
- ITIH5 | c.341G>A p.R114K | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs781704459, COSV56914037, COSV56917802; called by muse, mutect2, varscan2
- JCAD | c.1367G>A p.S456N | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as COSV100948545; called by muse, mutect2, varscan2
- JCAD | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.323); catalogued as COSV100948547; called by muse, mutect2, varscan2
- JMY | c.2938G>C p.A980P | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.491); catalogued as rs369808474, COSV101268104; called by muse, varscan2
- KALRN | c.3340C>T p.R1114C | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53783608; called by muse, mutect2, varscan2
- KCNB2 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs765031655, COSV73049534, COSV99074163; called by muse, mutect2, varscan2
- KCND3 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as COSV100138348; called by muse, mutect2, varscan2
- KCNH5 | c.1444C>T p.H482Y | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100527945; called by muse, mutect2, varscan2
- KCNQ3 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV101196389; called by muse, mutect2, varscan2
- KCNQ3 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.598); catalogued as COSV101196390; called by muse, mutect2, varscan2
- KCNU1 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 73/228 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.44); catalogued as rs773221041, COSV67759076; called by muse, mutect2, varscan2
- KCNV1 | c.1483G>A p.G495R | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV52086189; called by muse, mutect2, varscan2
- KIAA1210 | c.1233T>A p.N411K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as COSV101274371; called by muse, mutect2, varscan2
- KIF21B | c.4513G>A p.D1505N (on ENST00000422435 / NM_001252100.2; = p.D1492N on NM_017596.4) | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs144049379; called by muse, mutect2, varscan2
- KIF2A | c.457T>A p.S153T | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV101136663; called by muse, mutect2
- KLF15 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs1160068070, COSV56181096; called by muse, mutect2, varscan2
- KLRC1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as rs1375633111, COSV100760889; called by muse, mutect2, varscan2
- KRT77 | c.239G>T p.S80I | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.554); catalogued as rs200889592, COSV100527254; called by muse, mutect2, varscan2
- KSR1 | c.1429C>T p.P477S (on ENST00000644974 / NM_001367810.1; = p.P340S on NM_014238.2) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.966); catalogued as COSV52042282; called by muse, mutect2, varscan2
- KSR1 | c.1430C>T p.P477L (on ENST00000644974 / NM_001367810.1; = p.P340L on NM_014238.2) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99260695; called by muse, mutect2, varscan2
- L1CAM | c.3187C>T p.L1063F | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT tolerated (0.5); PolyPhen benign (0.058); catalogued as rs1569544630, COSV62826599; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LIFR | c.2407G>A p.G803S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.514); catalogued as COSV99665331; called by muse, mutect2, varscan2
- LILRB1 | c.553G>A p.V185M (on ENST00000427581; = p.V149M on NM_006669.6) | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.079); catalogued as rs1464083982, COSV100207821; called by muse, varscan2
- LONP2 | c.1744G>A p.G582R | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV99589480; called by muse, mutect2, varscan2
- LRP1B | c.8784T>G p.N2928K | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV101260242; called by muse, mutect2, varscan2
- LRRK1 | c.3587C>A p.T1196K | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.096); catalogued as COSV99442847; called by muse, mutect2, varscan2
- LSS | c.1940C>T p.S647F | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100711031; called by muse, mutect2, varscan2
- LUZP4 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100904881; called by muse, mutect2, varscan2
- LYPD5 | c.132G>A p.M44I (on ENST00000377950 / NM_001031749.3; = p.M1? on NM_182573.2) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100935288; called by muse, mutect2, varscan2
- MAGED2 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV99514745; called by muse, mutect2, varscan2
- MAML3 | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs1480673317, COSV101558520; called by muse, mutect2, varscan2
- MAML3 | c.2134C>T p.P712S | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV101558521, COSV72210237; called by muse, mutect2, varscan2
- MAP3K19 | c.3190G>A p.G1064S | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59640892; called by muse, mutect2, varscan2
- MARK1 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV100857531, COSV65069774; called by muse, mutect2, varscan2
- MED22 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100648131; called by muse, mutect2, varscan2
- MGAT4C | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749782221, COSV59833060; called by muse, mutect2, varscan2
- MN1 | c.3455C>T p.P1152L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1266340952, COSV100180041, COSV100180115; called by muse, mutect2, varscan2
- MOSPD1 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV100887863; called by muse, mutect2, varscan2
- MROH2B | c.2137C>T p.P713S | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as rs755447092, COSV68187775; called by muse, mutect2, varscan2
- MSH4 | c.1490T>A p.F497Y | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as COSV99592456; called by muse, mutect2, varscan2
- MTMR7 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 138/449 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99472710; called by muse, mutect2, varscan2
- MUC16 | c.12756G>A p.M4252I | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs751329146, COSV67482108; called by muse, mutect2, varscan2
- MUC16 | c.2755G>A p.E919K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); catalogued as COSV101201380; called by muse, mutect2, varscan2
- MUC17 | c.8546C>T p.S2849L | Missense Mutation (SNP) | VAF 185/503 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.587); catalogued as rs139270811, COSV60296042; called by muse, mutect2, varscan2
- MUC7 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 101/235 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.163); catalogued as COSV100512374; called by muse, mutect2, varscan2
- MYCBPAP | c.2336C>T p.S779F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99277350; called by muse, mutect2, varscan2
- MYF6 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as rs752195466, COSV99952926; called by muse, mutect2, varscan2
- MYH1 | c.2621G>A p.R874K | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV99876756; called by muse, mutect2, varscan2
- MYH4 | c.2662A>G p.K888E | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99702105; called by muse, mutect2, varscan2
- MYH8 | c.1612G>A p.E538K | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101238707, COSV67972503; called by muse, mutect2, varscan2
- MYO3B | c.1370G>A p.G457E | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100511562; called by muse, mutect2
- MYO3B | c.3299G>A p.G1100E | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100511563; called by muse, mutect2, varscan2
- MYO9B | c.6175C>T p.P2059S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV99812617; called by muse, mutect2, varscan2
- NEB | c.6265C>T p.H2089Y | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV99427392; called by muse, mutect2, varscan2
- NEK2 | c.772C>T p.H258Y | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100878756; called by muse, mutect2, varscan2
- NID1 | c.1751C>T p.S584F | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.171); catalogued as COSV99938235; called by muse, mutect2, varscan2
- NIPBL | c.1847G>A p.S616N | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs371073215; called by muse, mutect2, varscan2
- NOSTRIN | c.454C>T p.Q152* (on ENST00000317647 / NM_001039724.4; = p.Q74* on NM_052946.3) | Nonsense Mutation (SNP) | VAF 21/57 reads (37%) | catalogued as COSV100474007; called by muse, mutect2, varscan2
- NPAP1 | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 63/158 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV61508817; called by muse, mutect2, varscan2
- NRDE2 | c.2687C>T p.P896L | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV62965020; called by muse, mutect2, varscan2
- NUP205 | c.1619G>T p.S540I | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.321); catalogued as COSV99607523; called by muse, mutect2, varscan2
- NUP210 | c.4595C>T p.S1532F | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.065); catalogued as rs1220845827, COSV99596011; called by muse, mutect2, varscan2
- NWD1 | c.2848G>A p.D950N | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as rs564513398, COSV60338626; called by muse, mutect2, varscan2
- OPRPN | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); catalogued as rs952969590, COSV68193528; called by muse, mutect2, varscan2
- OR2B3 | c.365G>A p.R122K | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101013851, COSV65850873; called by muse, mutect2, varscan2
- OR2C1 | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100515077, COSV59240271; called by muse, mutect2, varscan2
- OR2C3 | c.915G>A p.M305I | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV63575085; called by muse, varscan2
- OR2M5 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 57/289 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100822872; called by muse, mutect2, varscan2
- OR3A3 | c.922G>A p.G308S | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as COSV99351468; called by muse, mutect2
- OR4A47 | c.362A>T p.Y121F | Missense Mutation (SNP) | VAF 50/92 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.761); catalogued as rs765513782, COSV101487097; called by muse, mutect2
- OR52E2 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV100384849; called by muse, mutect2, varscan2
- OR52M1 | c.253G>A p.G85R | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.265); catalogued as COSV100798614; called by muse, mutect2, varscan2
- OR5W2 | c.69G>A p.M23I | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs868531624, COSV60615735; called by muse, varscan2
- OR5W2 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs566367099, COSV100747736, COSV60616510; called by muse, varscan2
- P2RX1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV99844923; called by muse, mutect2, varscan2
- P2RY14 | c.588G>A p.W196* | Nonsense Mutation (SNP) | VAF 37/108 reads (34%) | catalogued as COSV99854478; called by muse, mutect2, varscan2
- PARD3 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs547955907, COSV60749757; called by muse, mutect2, varscan2
- PARD3B | c.1565G>A p.G522E | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100595021; called by muse, mutect2
- PAX9 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.127); catalogued as rs866470249, COSV100492308; called by muse, mutect2, varscan2
- PCDH11X | c.2333A>T p.N778I | Missense Mutation (SNP) | VAF 64/171 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100014702; called by muse, mutect2, varscan2
- PCDH18 | c.1538C>T p.S513F | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV61267168; called by muse, mutect2, varscan2
- PCDHA11 | c.2168C>T p.S723L | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.11); catalogued as rs1369255733, COSV56504636; called by muse, mutect2, varscan2
- PCDHB13 | c.2344G>A p.E782K | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as rs138168445, COSV99507773; called by muse, mutect2, varscan2
- PCDHGA8 | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as COSV53928289; called by muse, mutect2, varscan2
- PCDHGB5 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 27/41 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV53979006; called by muse, mutect2, varscan2
- PCNX2 | c.2750T>C p.L917P | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV50805939; called by muse, mutect2, varscan2
- PCNX2 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 41/76 reads (54%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.006); catalogued as COSV99269318; called by muse, mutect2, varscan2
- PDE1C | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.314); catalogued as COSV100373672; called by muse, mutect2, varscan2
- PDGFC | c.206G>A p.R69K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99926107; called by muse, mutect2, varscan2
- PDGFRB | c.790T>A p.F264I | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT tolerated (0.29); PolyPhen benign (0.102); catalogued as COSV99940922; called by muse, mutect2, varscan2
- PDZD7 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99827579; called by muse, mutect2, varscan2
- PELP1 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.425); catalogued as rs764771503, COSV99343325; called by muse, mutect2, varscan2
- PELP1 | c.1438G>A p.G480R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as rs750166392, COSV99343332; called by muse, mutect2, varscan2
- PFKFB1 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 104/238 reads (44%) | PolyPhen benign (0.039); catalogued as COSV100895837; called by muse, mutect2, varscan2
- PGBD1 | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 32/76 reads (42%) | catalogued as COSV99460872; called by muse, mutect2, varscan2
- PHACTR1 | c.1124A>T p.N375I | Missense Mutation (SNP) | VAF 59/153 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as COSV100276610, COSV100278688; called by muse, mutect2, varscan2
- PHF7 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.879); catalogued as COSV100015566; called by muse, mutect2, varscan2
- PIK3AP1 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100226180; called by muse, mutect2, varscan2
- PKD1 | c.9659C>T p.S3220L | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144246138; called by muse, mutect2, varscan2
- PKHD1 | c.4622G>A p.R1541K | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.053); catalogued as COSV100584419; called by muse, mutect2, varscan2
- PLA2G4C | c.1216C>T p.L406F | Missense Mutation (SNP) | VAF 63/150 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV100844037; called by muse, mutect2, varscan2
- PLEKHH2 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | catalogued as COSV99175069; called by muse, mutect2, varscan2
- PNLIP | c.766A>T p.K256* | Nonsense Mutation (SNP) | VAF 48/100 reads (48%) | catalogued as COSV100981954; called by muse, mutect2, varscan2
- PODN | c.1496G>A p.R499Q (on ENST00000395871; = p.R451Q on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.284); catalogued as rs372626429; called by muse, mutect2, varscan2
- POU5F2 | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV101232930; called by muse, mutect2, varscan2
- PRSS55 | c.716A>T p.K239M | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.886); catalogued as COSV100153876, COSV100153922; called by muse, mutect2, varscan2
- PSEN1 | c.761C>T p.S254L | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99998092; called by muse, mutect2, varscan2
- PSG1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 112/308 reads (36%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.773); catalogued as COSV54950260; called by muse, mutect2, varscan2
- PSG9 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 107/272 reads (39%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs866050640, COSV52483314; called by muse, mutect2, varscan2
- PTPRD | c.2524C>T p.Q842* | Nonsense Mutation (SNP) | VAF 39/49 reads (80%) | catalogued as COSV100646620; called by muse, mutect2, varscan2
- PTPRK | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs868427142, COSV63894383; called by muse, mutect2, varscan2
- PYGO1 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 56/122 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100114818; called by muse, mutect2, varscan2
- PZP | c.1439G>A p.R480K | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV99739230; called by muse, mutect2, varscan2
- RAB35 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV99984698; called by muse, mutect2, varscan2
- RABGAP1L | c.416G>T p.C139F | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99273781; called by muse, mutect2, varscan2
- RBP3 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.692); catalogued as rs576373730; called by muse, mutect2, varscan2
- RELN | c.2842G>A p.V948M | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100634790; called by muse, mutect2, varscan2
- RHAG | c.1138G>A p.G380S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100006838; called by muse, mutect2, varscan2
- RNF10 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.802); catalogued as COSV100378959; called by muse, mutect2, varscan2
- ROR1 | c.2201C>T p.S734F | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV100935547; called by muse, mutect2, varscan2
- RP1L1 | c.2792G>A p.G931E | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs763665045, COSV66754723; called by muse, mutect2, varscan2
- RRM1 | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 20/56 reads (36%) | catalogued as COSV100331449; called by muse, mutect2, varscan2
- RSPH3 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs546435437, COSV51922159; called by muse, mutect2, varscan2
- RUNX1T1 | c.728G>A p.R243Q (on ENST00000265814 / NM_001198628.1; = p.R216Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs779166132, COSV56138575, COSV56148911, COSV56149532; called by muse, mutect2, varscan2
- SATB1 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100113432; called by muse, mutect2, varscan2
- SCN10A | c.5479G>A p.E1827K | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs757155232, COSV101479516; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SERPINB11 | c.831G>A p.M277I | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV101236320; called by muse, mutect2, varscan2
- SERPINB5 | c.735G>A p.K245= | Splice Region (SNP) | VAF 9/32 reads (28%) | catalogued as COSV101237691; called by muse, mutect2, varscan2
- SERPINF2 | c.84G>A p.M28I | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV100131654; called by muse, mutect2
- SHROOM1 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as COSV100167247; called by muse, mutect2, varscan2
- SI | c.1735C>T p.P579S | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs914960775, COSV52265279; called by muse, mutect2, varscan2
- SI | c.1006C>T p.Q336* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV52290758; called by muse, mutect2, varscan2
- SKAP2 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.223); catalogued as rs982512587, COSV61725026; called by muse, mutect2, varscan2
- SLC12A1 | c.2557G>T p.E853* | Nonsense Mutation (SNP) | VAF 50/122 reads (41%) | catalogued as COSV101119310; called by muse, mutect2, varscan2
- SLC14A2 | c.1955G>A p.G652E | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99676109; called by muse, mutect2, varscan2
- SLC25A14 | c.717C>T p.F239= | Splice Region (SNP) | VAF 32/72 reads (44%) | catalogued as rs763425958, COSV99502596, COSV99502640; called by muse, mutect2, varscan2
- SLC30A6 | c.584T>A p.L195H | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs769663894, COSV99250068; called by muse, mutect2, varscan2
- SLC38A4 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV99873103; called by muse, mutect2, varscan2
- SLC5A9 | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99361944; called by muse, mutect2, varscan2
- SLC8A1 | c.2885C>T p.S962F | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV60478236; called by muse, mutect2, varscan2
- SLF2 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV99489676; called by muse, mutect2, varscan2
- SMAD7 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762653395, COSV100053049; called by muse, mutect2, varscan2
- SMAD7 | c.1165C>T p.P389S | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100053052; called by muse, mutect2, varscan2
- SMARCA1 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100946693; called by muse, mutect2, varscan2
- SMPD3 | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as rs759989372, COSV54711209; called by muse, mutect2, varscan2
- SNAP25 | c.478C>T p.L160F | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99655314; called by muse, mutect2, varscan2
- SPATA16 | c.1661G>A p.R554Q | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs549390160, COSV63526833, COSV63526919; called by muse, mutect2, varscan2
- SPATC1 | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.332); catalogued as COSV101085275; called by muse, mutect2, varscan2
- SPINK5 | c.1651G>A p.G551R | Missense Mutation (SNP) | VAF 33/43 reads (77%) | SIFT tolerated (0.29); PolyPhen benign (0.102); catalogued as rs762756312, COSV56260532; called by muse, mutect2, varscan2
- SPTBN5 | c.2537C>T p.P846L | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0.065); catalogued as COSV100312104; called by muse, mutect2
- SPZ1 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.084); catalogued as COSV99698266; called by muse, mutect2, varscan2
- SRMS | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV53920381; called by muse, varscan2
- SRRM2 | c.7895C>T p.S2632F | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs779595105, COSV51940068, COSV99241706; called by muse, mutect2, varscan2
- SSR2 | c.193C>T p.P65S | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as COSV55303900; called by muse, mutect2, varscan2
- ST18 | c.1781A>G p.N594S | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.828); catalogued as COSV99390905; called by muse, mutect2, varscan2
- STAB1 | c.3581G>A p.G1194E | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1444359514, COSV100402167; called by muse, mutect2, varscan2
- STXBP5 | c.2708C>T p.P903L (on ENST00000321680 / NM_001127715.2; = p.P867L on NM_139244.4) | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99470890; called by muse, mutect2, varscan2
- SULF1 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV52688851; called by muse, mutect2, varscan2
- SVEP1 | c.6383G>A p.R2128K | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV99929678; called by muse, mutect2, varscan2
- SYK | c.1670G>A p.S557N | Missense Mutation (SNP) | VAF 72/107 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101002603; called by muse, mutect2, varscan2
- SYNE1 | c.1152G>C p.L384F (on ENST00000367255 / NM_182961.4; = p.L391F on NM_033071.3) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV99576708; called by muse, mutect2, varscan2
- TACC2 | c.3745G>A p.E1249K | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); catalogued as COSV57747456, COSV57756722; called by muse, mutect2, varscan2
- TBC1D14 | c.1639C>G p.H547D | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV101299036; called by muse, mutect2, varscan2
- TCP11L2 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.771); catalogued as COSV54429922; called by muse, mutect2, varscan2
- TFDP3 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100033463, COSV100033518; called by muse, mutect2, varscan2
- TGFBR3 | c.2116G>A p.E706K | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99283612; called by muse, mutect2, varscan2
- THSD7B | c.869C>T p.S290L | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs200250890, COSV55707540; called by muse, mutect2, varscan2
- TIGD4 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs780128881, COSV58549437; called by muse, mutect2, varscan2
- TIMP2 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.248); catalogued as rs151117827; called by muse, mutect2, varscan2
- TLE2 | c.944C>T p.P315L | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs570019503, COSV53584377; called by muse, mutect2, varscan2
- TLR5 | c.1967C>T p.T656I | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV100643375; called by muse, mutect2, varscan2
- TMCO4 | c.367T>G p.F123V | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99617495; called by muse, mutect2, varscan2
- TMEM117 | c.1235G>A p.W412* | Nonsense Mutation (SNP) | VAF 22/92 reads (24%) | catalogued as COSV56906478, COSV99863562; called by muse, mutect2, varscan2
- TMEM132B | c.2422C>T p.R808W | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs775349963, COSV100170770; called by muse, mutect2, varscan2
- TNRC6C | c.1736C>T p.S579F | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV100050598; called by muse, mutect2, varscan2
- TNS4 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as COSV99564117; called by muse, mutect2, varscan2
- TRANK1 | c.8677G>A p.G2893S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV100084561; called by muse, mutect2, varscan2
- TRIM71 | c.2386C>T p.R796C | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1455479185, COSV101070493; called by muse, mutect2, varscan2
- TRIM73 | c.652A>G p.T218A | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100099875; called by muse, mutect2, varscan2
- TRPC6 | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as rs267602664, CM156589, CM158444, COSV60251176; called by muse, mutect2, varscan2
- TRPC7 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV61452471; called by muse, mutect2, varscan2
- TSPAN2 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs753573127, COSV65690375; called by muse, mutect2, varscan2
- TSPAN3 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV99144474; called by muse, mutect2, varscan2
- TTC14 | c.598C>T p.H200Y | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV56009968, COSV99932333; called by muse, mutect2, varscan2
- TTN | c.88682C>T p.S29561F (on ENST00000591111; = p.S22137F on NM_003319.4) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | PolyPhen possibly damaging (0.549); catalogued as rs868211733, COSV100627608; called by muse, mutect2, varscan2
- TTN | c.9140C>T p.S3047L (on ENST00000591111; = p.S3001L on NM_003319.4) | Missense Mutation (SNP) | VAF 20/47 reads (43%) | PolyPhen benign (0.436); catalogued as COSV100627613; called by muse, mutect2, varscan2
- UBL7 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 57/137 reads (42%) | catalogued as COSV100795452; called by muse, mutect2, varscan2
- UBN2 | c.3617C>T p.P1206L | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV99944404; called by muse, mutect2, varscan2
- UGT1A1 | c.419T>C p.L140P | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100530930; called by muse, mutect2, varscan2
- UGT1A7 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 105/299 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs144940363, COSV60845066; called by muse, mutect2
- UGT2B17 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 143/410 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.211); catalogued as COSV100497297; called by muse, mutect2, varscan2
- ULBP3 | c.400G>T p.G134* | Nonsense Mutation (SNP) | VAF 46/111 reads (41%) | catalogued as COSV100949656; called by muse, mutect2, varscan2
- UNC79 | c.2884G>A p.E962K (on ENST00000393151 / NM_001346218.2; = p.E785K on NM_020818.5) | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as rs767259575, COSV56373893; called by muse, mutect2, varscan2
- USP29 | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as COSV99518581; called by muse, mutect2, varscan2
- UTRN | c.5260G>A p.E1754K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as COSV100840536; called by muse, mutect2, varscan2
- VCAM1 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99658864; called by muse, mutect2, varscan2
- VPS29 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100804914; called by muse, mutect2, varscan2
- VWA7 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as rs1562284974, COSV100791854; called by muse, mutect2, varscan2
- WRN | c.1787C>T p.S596F | Missense Mutation (SNP) | VAF 48/105 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); catalogued as COSV53305996, COSV99989781; called by muse, mutect2, varscan2
- XPR1 | c.447+1G>A p.X149_splice | Splice Site (SNP) | VAF 30/56 reads (54%) | catalogued as COSV100851512; called by muse, mutect2, varscan2
- XPR1 | c.447+2T>A p.X149_splice | Splice Site (SNP) | VAF 30/55 reads (55%) | catalogued as COSV100851513; called by muse, mutect2, varscan2
- ZDBF2 | c.2321G>A p.R774Q | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.098); catalogued as rs200895636; called by muse, mutect2, varscan2
- ZFHX4 | c.8611C>T p.P2871S | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs373682555; called by muse, mutect2
- ZFR2 | c.1322C>T p.P441L | Missense Mutation (SNP) | VAF 62/145 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs761008204, COSV53601174; called by muse, mutect2, varscan2
- ZHX3 | c.1474C>T p.L492F | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV100476678; called by muse, mutect2, varscan2
- ZNF266 | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV63221885; called by muse, mutect2, varscan2
- ZNF285 | c.1102G>A p.G368R | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV100450127; called by muse, mutect2, varscan2
- ZNF470 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 39/77 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.607); catalogued as COSV100401381; called by muse, mutect2, varscan2
- ZNF573 | c.1769C>T p.A590V (on ENST00000536220 / NM_001172692.1; = p.A532V on NM_152360.3) | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); catalogued as COSV100265824, COSV59826878; called by muse, mutect2, varscan2
- ZNF573 | c.1344A>T p.K448N (on ENST00000536220 / NM_001172692.1; = p.K390N on NM_152360.3) | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV100265826; called by muse, mutect2, varscan2
- ZNF585B | c.1226C>T p.S409L | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as rs368332359; called by muse, mutect2, varscan2
- ZNF597 | c.1199C>T p.T400I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV100072140; called by muse, mutect2, varscan2
- ZNF615 | c.1586G>A p.G529E | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as COSV100943946; called by muse, mutect2, varscan2
- ZNF711 | c.2222G>A p.G741E | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV99341543; called by muse, mutect2, varscan2
- ZSCAN5A | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV99570638; called by muse, mutect2, varscan2
- IGHV1-24 | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 74/197 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- IGHV3-20 | c.269C>T p.S90F | Missense Mutation (SNP) | VAF 127/338 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- PALD1 | c.162_175del p.K55Cfs*14 | Frame Shift Del (DEL) | VAF 16/46 reads (35%) | called by mutect2, pindel, varscan2
- TRAJ7 | c.53T>G p.V18G | Missense Mutation (SNP) | VAF 23/65 reads (35%) | called by muse, mutect2, varscan2
- TRAV1-1 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ABCA12 | c.7473G>A p.K2491= (on ENST00000272895 / NM_173076.3; = p.K2173= on NM_015657.3) | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs543222287, COSV99791735; called by muse, mutect2, varscan2
- ABHD17B | c.642C>T p.F214= | Silent (SNP) | VAF 30/41 reads (73%) | catalogued as rs757880312, COSV100330288; called by muse, mutect2, varscan2
- ACSL3 | c.444A>G p.G148= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV100658093; called by muse, mutect2, varscan2
- ADGRL3 | c.3264C>T p.F1088= (on ENST00000506720 / NM_001322402.2; = p.F1020= on NM_015236.6) | Silent (SNP) | VAF 40/111 reads (36%) | catalogued as COSV72231855; called by muse, mutect2, varscan2
- ALKBH3 | c.252C>T p.P84= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as COSV100236557; called by muse, mutect2, varscan2
- ALOX15 | c.1305C>T p.F435= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV99541725; called by muse, mutect2, varscan2
- ANAPC1 | c.5667C>T p.L1889= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as rs772269461, COSV61977217; called by muse, mutect2, varscan2
- ARMCX5 | c.132G>A p.L44= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as COSV99863543; called by muse, mutect2, varscan2
- ASTN1 | c.663C>T p.R221= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs759575707, COSV99922903; called by muse, mutect2, varscan2
- AZIN2 | c.252G>A p.L84= | Silent (SNP) | VAF 41/114 reads (36%) | catalogued as COSV99613741; called by muse, mutect2, varscan2
- BCL2L11 | c.105C>T p.S35= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV100427480; called by muse, mutect2, varscan2
- BPIFB2 | c.282A>G p.A94= | Silent (SNP) | VAF 52/158 reads (33%) | catalogued as COSV99401647; called by muse, mutect2, varscan2
- BRPF3 | c.453G>A p.E151= | Silent (SNP) | VAF 24/58 reads (41%) | catalogued as COSV100326152; called by muse, mutect2, varscan2
- BRWD3 | c.4407G>A p.G1469= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as rs1356294243, COSV100956463; called by muse, mutect2, varscan2
- C8B | c.1512C>T p.H504= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV100980896; called by muse, mutect2, varscan2
- CADM4 | c.489G>A p.K163= | Silent (SNP) | VAF 60/169 reads (36%) | catalogued as COSV99731678; called by muse, mutect2, varscan2
- CD8B | c.723G>A p.L241= (on ENST00000331469 / NM_172213.4; = p.L211= on NM_172102.4) | Silent (SNP) | VAF 192/478 reads (40%) | catalogued as COSV58925383; called by muse, mutect2, varscan2
- CDH20 | c.2310G>A p.S770= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs369949747; called by muse, varscan2
- CEP41 | c.1038G>A p.Q346= | Silent (SNP) | VAF 95/260 reads (37%) | catalogued as COSV99782893; called by muse, mutect2, varscan2
- CFAP126 | c.291G>A p.Q97= | Silent (SNP) | VAF 77/176 reads (44%) | catalogued as COSV100713764; called by muse, mutect2, varscan2
- CFAP45 | c.615C>T p.A205= | Silent (SNP) | VAF 79/214 reads (37%) | catalogued as rs753338367, COSV100928661; called by muse, mutect2, varscan2
- CHRNB3 | c.1176G>A p.L392= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as COSV99251442; called by muse, mutect2, varscan2
- CNTN4 | c.2484G>A p.K828= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV100639469, COSV100639668; called by muse, mutect2, varscan2
- CNTN6 | c.684G>A p.K228= | Silent (SNP) | VAF 37/120 reads (31%) | catalogued as COSV100611217, COSV100611761; called by muse, mutect2, varscan2
- CPXM2 | c.2235G>A p.L745= | Silent (SNP) | VAF 43/78 reads (55%) | catalogued as rs994767496, COSV99583225; called by muse, mutect2, varscan2
- CPXM2 | c.2097C>T p.S699= | Silent (SNP) | VAF 47/219 reads (21%) | catalogued as COSV99583228; called by muse, mutect2, varscan2
- CRTAC1 | c.396C>T p.F132= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs1197823512, COSV100086080; called by muse, mutect2, varscan2
- CTSF | c.669C>T p.A223= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV100074481; called by muse, mutect2, varscan2
- CUX1 | c.2385C>T p.D795= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV99472907; called by muse, mutect2, varscan2
- CYP2U1 | c.1533C>T p.F511= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as rs372600671; called by muse, mutect2, varscan2
- DCAF4L2 | c.117C>T p.F39= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as rs779092689, COSV60476339; called by muse, mutect2, varscan2
- DCC | c.3987A>G p.R1329= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as COSV101473496; called by muse, mutect2, varscan2
- DGKB | c.1596C>T p.C532= | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as COSV99342995; called by muse, mutect2, varscan2
- DIDO1 | c.3129G>A p.E1043= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs1568841416, COSV56625149, COSV99825400, COSV99826954; called by muse, mutect2, varscan2
- DNAH8 | c.9126C>T p.Y3042= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100547039; called by muse, mutect2, varscan2
- DNAJA4 | c.576C>T p.D192= (on ENST00000343789; = p.D221= on NM_018602.3) | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV100655242; called by muse, mutect2, varscan2
- DOCK3 | c.3825A>G p.L1275= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs201894970, COSV99814702; called by muse, mutect2, varscan2
- DRD5 | c.1101G>A p.K367= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as COSV100432013; called by muse, mutect2, varscan2
- DSG3 | c.2766C>T p.I922= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as rs372187590, COSV99934675; called by muse, mutect2
- EFHC2 | c.624G>A p.E208= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs774216331, COSV101375546; called by muse, mutect2, varscan2
- EGF | c.1413G>A p.L471= | Silent (SNP) | VAF 42/111 reads (38%) | catalogued as COSV99491328; called by muse, mutect2, varscan2
- EHMT2 | c.1941C>T p.L647= | Silent (SNP) | VAF 37/101 reads (37%) | catalogued as COSV100977240; called by muse, mutect2, varscan2
- EPHA3 | c.2358C>T p.I786= | Silent (SNP) | VAF 41/95 reads (43%) | catalogued as COSV100348280; called by muse, mutect2, varscan2
- EPHB6 | c.1686G>A p.R562= | Silent (SNP) | VAF 50/112 reads (45%) | catalogued as COSV100844417; called by muse, mutect2, varscan2
- EPPK1 | c.6636G>A p.E2212= | Silent (SNP) | VAF 52/150 reads (35%) | catalogued as rs569459584, COSV73261088; called by muse, mutect2, varscan2
- EXOC3L2 | c.1464C>T p.F488= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99374636; called by muse, mutect2
- FASN | c.5754C>T p.S1918= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as rs541901851, COSV60761025, COSV60762681; called by muse, mutect2, varscan2
- FBP1 | c.783G>A p.G261= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV100941336; called by muse, mutect2, varscan2
- FOXR2 | c.402C>T p.S134= | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV100189603; called by muse, mutect2, varscan2
- GCOM1 | c.519C>T p.G173= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV51096321, COSV99985288; called by muse, mutect2
- GLCCI1 | c.1617C>T p.I539= | Silent (SNP) | VAF 82/197 reads (42%) | catalogued as COSV56206193, COSV99780710; called by muse, mutect2, varscan2
- GPR119 | c.294G>A p.L98= | Silent (SNP) | VAF 106/281 reads (38%) | catalogued as COSV99358709; called by muse, mutect2, varscan2
- GPR151 | c.156G>A p.V52= | Silent (SNP) | VAF 48/68 reads (71%) | catalogued as COSV99695233; called by muse, mutect2, varscan2
- GPR31 | c.936C>T p.F312= | Silent (SNP) | VAF 39/88 reads (44%) | catalogued as COSV100834169; called by muse, mutect2, varscan2
- GPR39 | c.711C>T p.S237= | Silent (SNP) | VAF 28/64 reads (44%) | catalogued as rs757784055, COSV100258475; called by muse, mutect2, varscan2
- GPR50 | c.102G>A p.A34= | Silent (SNP) | VAF 53/148 reads (36%) | catalogued as rs199790958, COSV54436682; called by muse, mutect2, varscan2
- GRAP2 | c.835C>T p.L279= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as rs749993287, COSV100703141; called by muse, mutect2, varscan2
- GRIN3A | c.1392C>T p.F464= | Silent (SNP) | VAF 71/116 reads (61%) | catalogued as COSV62451106; called by muse, mutect2, varscan2
- GRM3 | c.870C>T p.R290= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as rs750137951, COSV64470967; called by muse, mutect2, varscan2
- GTF3C2 | c.165C>T p.T55= | Silent (SNP) | VAF 91/216 reads (42%) | catalogued as rs764415890, COSV99273235; called by muse, mutect2, varscan2
- GUCY2C | c.3018G>A p.Q1006= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs1194096068, COSV99664100; called by muse, mutect2, varscan2
- HOXA6 | c.528C>T p.F176= | Silent (SNP) | VAF 86/213 reads (40%) | catalogued as rs750134271, COSV56072377, COSV56074833; called by muse, mutect2, varscan2
- HUWE1 | c.11566C>T p.L3856= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV99474040; called by muse, mutect2, varscan2
- IGHV3-23 | c.298C>T p.L100= | Silent (SNP) | VAF 114/487 reads (23%) | catalogued as rs566326210; called by muse, mutect2, varscan2
- ISM1 | c.567C>T p.F189= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as rs1264173872, COSV99340296; called by muse, mutect2, varscan2
- JAG1 | c.3075G>A p.G1025= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as rs764847570, COSV99653495; called by muse, mutect2, varscan2
- KALRN | c.741G>A p.R247= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV99567039; called by muse, mutect2, varscan2
- KCNH5 | c.1443C>T p.Y481= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV100527948; called by muse, mutect2, varscan2
- KCNH5 | c.441G>A p.T147= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as rs753750382, COSV59752889; called by muse, mutect2, varscan2
- KIAA1614 | c.3363C>T p.G1121= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as COSV100799884; called by muse, mutect2, varscan2
- LRFN5 | c.27T>C p.F9= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV99985291; called by muse, mutect2, varscan2
- LRRC18 | c.444G>A p.E148= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs267602501, COSV99630373, COSV99630606; called by muse, mutect2, varscan2
- MACF1 | c.20463G>A p.V6821= (on ENST00000372915; = p.V4866= on NM_012090.5) | Silent (SNP) | VAF 62/175 reads (35%) | catalogued as COSV99246527; called by muse, mutect2, varscan2
- MCTP2 | c.2385C>T p.F795= | Silent (SNP) | VAF 63/141 reads (45%) | catalogued as COSV63295371; called by muse, mutect2, varscan2
- MED22 | c.540C>T p.P180= | Silent (SNP) | VAF 16/23 reads (70%) | catalogued as rs1237048827, COSV100648130; called by muse, mutect2, varscan2
- MEF2B | c.660G>A p.G220= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV99364902; called by muse, mutect2, varscan2
- MIEF2 | c.1347G>A p.E449= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV100544144; called by muse, mutect2, varscan2
- MOB3B | c.480G>A p.R160= | Silent (SNP) | VAF 83/141 reads (59%) | catalogued as COSV99218903; called by muse, mutect2, varscan2
- MUC16 | c.15804G>A p.T5268= | Silent (SNP) | VAF 32/76 reads (42%) | catalogued as COSV101198873; called by muse, mutect2, varscan2
- MUC17 | c.11478G>A p.V3826= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV100074889; called by muse, mutect2, varscan2
- MXRA5 | c.7656C>T p.I2552= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99478994; called by muse, mutect2, varscan2
- MXRA5 | c.6015C>T p.H2005= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs758500843, COSV54235580; called by muse, mutect2, varscan2
- MYCBPAP | c.2337C>T p.S779= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99277352; called by muse, mutect2, varscan2
- MYH4 | c.750C>T p.F250= | Silent (SNP) | VAF 21/50 reads (42%) | catalogued as rs1244732876, COSV55111843, COSV55120205; called by muse, mutect2, varscan2
- MYO18B | c.7323C>T p.F2441= | Silent (SNP) | VAF 66/162 reads (41%) | catalogued as rs762049627, COSV59130595; called by muse, mutect2, varscan2
- NAIP | c.390G>A p.K130= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as COSV99519452; called by muse, mutect2, varscan2
- NAT2 | c.465G>A p.E155= | Silent (SNP) | VAF 33/63 reads (52%) | catalogued as COSV54061936; called by muse, mutect2
- NCOA6 | c.3591C>T p.F1197= | Silent (SNP) | VAF 56/147 reads (38%) | catalogued as COSV100750311; called by muse, mutect2, varscan2
- NEK2 | c.771C>T p.Y257= | Silent (SNP) | VAF 32/64 reads (50%) | catalogued as rs1159284015, COSV65355378; called by muse, mutect2, varscan2
- NID2 | c.864C>T p.S288= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as rs765118458, COSV99355984; called by muse, mutect2, varscan2
- NKAIN2 | c.444G>A p.V148= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as COSV100864048; called by muse, mutect2, varscan2
- NLRP1 | c.1077C>T p.D359= | Silent (SNP) | VAF 39/106 reads (37%) | catalogued as COSV99335332; called by muse, mutect2, varscan2
- NOL4 | c.1311C>T p.I437= | Silent (SNP) | VAF 26/41 reads (63%) | catalogued as COSV52340484; called by muse, mutect2, varscan2
- NOS1 | c.3900G>A p.E1300= | Silent (SNP) | VAF 38/120 reads (32%) | catalogued as COSV100501320; called by muse, mutect2, varscan2
- NXPH1 | c.393G>A p.V131= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as rs748163079, COSV101339792; called by muse, mutect2, varscan2
- OR2AT4 | c.264C>T p.S88= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV100532400, COSV100532420; called by muse, mutect2, varscan2
- OR2B6 | c.879G>A p.R293= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as COSV55128563; called by muse, mutect2, varscan2
- OR2T2 | c.405C>T p.L135= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as COSV100737792; called by muse, mutect2, varscan2
- OR51F1 | c.111C>T p.S37= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100598882; called by muse, mutect2, varscan2
- OR52E2 | c.792C>G p.R264= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV100384907; called by muse, mutect2, varscan2
- OR7E24 | c.72C>T p.L24= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as rs766876532, COSV101509684; called by muse, mutect2, varscan2
- OR7G1 | c.138C>T p.L46= | Silent (SNP) | VAF 41/175 reads (23%) | catalogued as COSV53319131, COSV99528779; called by muse, mutect2, varscan2
- OR8I2 | c.339C>T p.F113= | Silent (SNP) | VAF 52/122 reads (43%) | catalogued as COSV56167742; called by muse, mutect2, varscan2
- OR8K3 | c.501C>T p.S167= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as rs1268513314, COSV57131511; called by muse, mutect2, varscan2
- OTUD4 | c.2247C>T p.F749= (on ENST00000447906 / NM_001366057.1; = p.F684= on NM_001102653.1) | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as COSV101486052; called by muse, mutect2, varscan2
- PARD3B | c.942G>A p.L314= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV100595016; called by muse, mutect2, varscan2
- PCDH1 | c.1371C>T p.F457= | Silent (SNP) | VAF 74/103 reads (72%) | catalogued as COSV99746892; called by muse, mutect2, varscan2
- PCDH18 | c.1764C>T p.I588= | Silent (SNP) | VAF 83/224 reads (37%) | catalogued as COSV100787494, COSV61270214; called by muse, mutect2, varscan2
- PCDHB7 | c.2097C>T p.F699= | Silent (SNP) | VAF 80/351 reads (23%) | catalogued as rs1554280385, COSV50810122; called by muse, mutect2, varscan2
- PDE4DIP | c.6108C>T p.H2036= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as rs781917864, COSV100521505; called by muse, mutect2, varscan2
- PDGFC | c.933G>A p.L311= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as COSV99926106; called by muse, mutect2, varscan2
- PEG3 | c.1461C>T p.I487= | Silent (SNP) | VAF 47/125 reads (38%) | catalogued as COSV55627986, COSV55649421; called by muse, mutect2, varscan2
- PGGT1B | c.870C>T p.N290= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as COSV99686038; called by muse, mutect2
- PLCB4 | c.2493C>T p.I831= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs748785049, COSV53801217; ClinVar: likely benign; called by muse, mutect2, varscan2
- PMPCA | c.1221C>T p.I407= | Silent (SNP) | VAF 27/51 reads (53%) | catalogued as COSV100867834; called by muse, mutect2, varscan2
- PPP6R1 | c.2178C>T p.S726= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs369196770; called by muse, varscan2
- PPRC1 | c.3993C>T p.I1331= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99532049; called by muse, mutect2, varscan2
- PREP | c.1734G>A p.V578= (on ENST00000369110; = p.V644= on NM_002726.5) | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV100964113; called by muse, mutect2, varscan2
- PREX1 | c.2853C>T p.P951= | Silent (SNP) | VAF 51/127 reads (40%) | catalogued as COSV100906769; called by muse, mutect2, varscan2
- PRKAG3 | c.429G>A p.E143= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs774788437, COSV99292109; called by muse, mutect2, varscan2
- PRMT7 | c.891C>T p.A297= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as rs994972869, COSV100267230; called by muse, mutect2
- RASAL1 | c.1509C>T p.A503= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as rs541174055, COSV99922080; called by muse, mutect2, varscan2
- RBFOX1 | c.1131C>T p.L377= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as rs1251126279, COSV60949870; called by muse, mutect2, varscan2
- RFPL3 | c.558G>A p.V186= (on ENST00000249007 / NM_001098535.1; = p.V157= on NM_006604.2) | Silent (SNP) | VAF 20/109 reads (18%) | catalogued as COSV99967262; called by muse, mutect2, varscan2
- S1PR5 | c.804C>T p.F268= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV100330796; called by muse, mutect2, varscan2
- SACS | c.6030G>A p.K2010= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV101207693; called by muse, mutect2, varscan2
- SALL3 | c.3153C>T p.S1051= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs1293915081, COSV101610049; called by muse, mutect2, varscan2
- SCN11A | c.3990G>A p.K1330= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV100182390; called by muse, mutect2, varscan2
- SCN2A | c.1542T>G p.S514= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99333255; called by muse, mutect2, varscan2
- SEPTIN6 | c.984G>A p.R328= | Silent (SNP) | VAF 82/215 reads (38%) | catalogued as COSV59715919; called by muse, mutect2, varscan2
- SGCG | c.180G>A p.V60= | Silent (SNP) | VAF 19/72 reads (26%) | catalogued as rs919571338, COSV99523363; called by muse, mutect2, varscan2
- SIM1 | c.297G>A p.G99= | Silent (SNP) | VAF 66/173 reads (38%) | catalogued as rs1288213195, COSV99492716; called by muse, mutect2, varscan2
- SIRPD | c.216G>A p.R72= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV67547459; called by muse, mutect2, varscan2
- SLC10A2 | c.912C>T p.F304= | Silent (SNP) | VAF 50/124 reads (40%) | catalogued as COSV55362764; called by muse, mutect2, varscan2
- SLC16A11 | c.1024C>T p.L342= (on ENST00000308009; = p.L318= on NM_153357.3) | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100338748; called by muse, mutect2, varscan2
- SLC47A1 | c.1464C>T p.L488= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs1399567593, COSV99565611; called by muse, mutect2, varscan2
- SLC7A8 | c.660G>A p.K220= | Silent (SNP) | VAF 66/161 reads (41%) | catalogued as COSV100328567; called by muse, mutect2, varscan2
- SLCO1B3 | c.1842G>A p.R614= | Silent (SNP) | VAF 28/78 reads (36%) | catalogued as rs1417169342, COSV53934310; called by muse, mutect2, varscan2
- SORCS3 | c.3600C>T p.V1200= | Silent (SNP) | VAF 20/35 reads (57%) | catalogued as COSV100865641, COSV63803556; called by muse, mutect2, varscan2
- SPHKAP | c.2304C>T p.S768= | Silent (SNP) | VAF 50/122 reads (41%) | catalogued as COSV100764512; called by muse, mutect2, varscan2
- ST6GAL2 | c.609C>T p.F203= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs745800013, COSV100868262; called by muse, mutect2, varscan2
- SVEP1 | c.975G>A p.S325= | Silent (SNP) | VAF 13/16 reads (81%) | catalogued as rs373483379, COSV100238632; called by muse, mutect2, varscan2
- TBC1D14 | c.1638C>T p.D546= | Silent (SNP) | VAF 45/133 reads (34%) | catalogued as COSV101299035; called by muse, mutect2, varscan2
- TBC1D19 | c.1533A>G p.L511= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV99336766; called by muse, mutect2, varscan2
- TCHHL1 | c.1617C>T p.F539= | Silent (SNP) | VAF 52/118 reads (44%) | catalogued as COSV64286917; called by muse, mutect2, varscan2
- TCTN1 | c.1752C>T p.F584= (on ENST00000551590 / NM_001173975.3; = p.F570= on NM_024549.6) | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV99657429; called by muse, mutect2, varscan2
- TMEM161A | c.831C>T p.P277= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV99365571; called by muse, mutect2, varscan2
- TMEM200A | c.1041G>A p.R347= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs267600808, COSV51651813; called by muse, mutect2, varscan2
- TMEM243 | c.339C>T p.F113= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV99991503; called by muse, mutect2, varscan2
- TMEM92 | c.144G>A p.E48= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV100305232; called by muse, mutect2, varscan2
- TRANK1 | c.5961G>A p.E1987= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs1017891514, COSV100084410, COSV100084566; called by muse, mutect2, varscan2
- TRIM60 | c.1119G>A p.R373= | Silent (SNP) | VAF 45/128 reads (35%) | catalogued as COSV100594115; called by muse, mutect2, varscan2
- TTC13 | c.1614C>T p.V538= | Silent (SNP) | VAF 55/115 reads (48%) | catalogued as COSV100793008; called by muse, mutect2, varscan2
- TTN | c.30303A>C p.A10101= (on ENST00000591111; = p.A9174= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV100627610; called by muse, varscan2
- TTN | c.13161G>A p.R4387= (on ENST00000591111; = p.R4341= on NM_003319.4) | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV59883629; called by muse, mutect2, varscan2
- TTN | c.8538G>A p.R2846= (on ENST00000591111; = p.R2800= on NM_003319.4) | Silent (SNP) | VAF 37/124 reads (30%) | catalogued as COSV100627614; called by muse, mutect2, varscan2
- UFC1 | c.166C>T p.L56= | Silent (SNP) | VAF 105/262 reads (40%) | catalogued as COSV99237743; called by muse, mutect2, varscan2
- UGT2B15 | c.504C>T p.P168= | Silent (SNP) | VAF 42/331 reads (13%) | catalogued as rs1371040151, COSV57734530; called by muse, mutect2, varscan2
- USH1G | c.561C>T p.S187= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as COSV100140614; called by muse, mutect2, varscan2
- VIPR2 | c.315C>T p.F105= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as rs186398445, COSV51103495; called by muse, mutect2, varscan2
- XKR6 | c.1650A>G p.Q550= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs570199792, COSV100441075; called by muse, mutect2, varscan2
- ZBED9 | c.2544C>T p.I848= | Silent (SNP) | VAF 54/144 reads (38%) | catalogued as rs1414377863, COSV71729577; called by muse, mutect2, varscan2
- ZFP36L1 | c.726C>T p.T242= | Silent (SNP) | VAF 35/130 reads (27%) | catalogued as rs1241700482, COSV60545797; called by muse, mutect2, varscan2
- ZHX3 | c.1473C>T p.F491= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as COSV100476680; called by muse, mutect2, varscan2
- ZNF425 | c.1410C>T p.F470= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as rs758330922, COSV100955588; called by muse, mutect2, varscan2
- ZNF479 | c.303G>A p.Q101= | Silent (SNP) | VAF 42/134 reads (31%) | catalogued as COSV58641355; called by muse, mutect2, varscan2
- ZNF518A | c.2310C>T p.L770= | Silent (SNP) | VAF 4/26 reads (15%) | catalogued as COSV100283710; called by muse, mutect2, varscan2
- ZNF676 | c.96G>A p.V32= | Silent (SNP) | VAF 78/217 reads (36%) | catalogued as COSV101236330; called by muse, mutect2, varscan2
- ZNF711 | c.1743G>A p.L581= | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99341542; called by muse, mutect2, varscan2
- ZNF773 | c.735G>A p.R245= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as COSV99989507; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73822362 G>A | 5'Flank (SNP) | VAF 6/10 reads (60%) | called by muse, varscan2
- ANKRD13D | c.*679C>T | 3'UTR (SNP) | VAF 45/126 reads (36%) | catalogued as COSV100398601; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499014 C>T | 5'Flank (SNP) | VAF 36/101 reads (36%) | called by muse, mutect2, varscan2
- CCDC28A | c.-55C>T | 5'UTR (SNP) | VAF 51/118 reads (43%) | catalogued as rs775293748, COSV100236620; called by muse, mutect2, varscan2
- FREM1 | c.4857+1642C>T | Intron (SNP) | VAF 69/101 reads (68%) | catalogued as rs768533000; called by muse, mutect2, varscan2
- HMGN2P46 | n.971G>A | RNA (SNP) | VAF 21/65 reads (32%) | catalogued as rs369397044; called by muse, mutect2, varscan2
- MIR487B | n.54C>T | RNA (SNP) | VAF 22/52 reads (42%) | catalogued as rs1402013521; called by muse, mutect2, varscan2
- PARP15 | c.772-42T>A | Intron (SNP) | VAF 17/45 reads (38%) | catalogued as COSV100117197; called by muse, mutect2, varscan2
- RNF217-AS1 | n.2810A>G | RNA (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- SLC25A48 | c.679+152C>T | Intron (SNP) | VAF 9/33 reads (27%) | catalogued as rs373574923; called by muse, mutect2, varscan2
- ZNF658B | n.1293C>T | RNA (SNP) | VAF 55/100 reads (55%) | called by muse, mutect2, varscan2
